Somatic mutation profile of tumor specimen HTMCP-03-06-02425-01A (aliquot HTMCP-03-06-02425-01A-01D-10409) from CGCI case HTMCP-03-06-02425, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G3.
Specimen HTMCP-03-06-02425-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7eba5c28-84ff-4ffa-8251-859738552ec2.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02425-10A (Blood Derived Normal), aliquot HTMCP-03-06-02425-10A-01D-10409; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d6053905-7907-401d-8139-ca02ee24badc

The open-access MAF lists 23 somatic variants for this specimen: 16 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 5, RNA 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARFIP2 | c.52G>A p.G18R | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.561); catalogued as rs527788217, COSV54446814; called by mutect2, varscan2
- ATRX | c.6332G>A p.R2111Q | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64875280; called by muse, mutect2, varscan2
- CEP290 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776101043, COSV58349805; called by muse, mutect2, varscan2
- CRB1 | c.1282C>A p.L428I | Missense Mutation (SNP) | VAF 38/202 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV100957595; called by muse, mutect2, varscan2
- DLG4 | c.1262C>T p.A421V (on ENST00000399506 / NM_001321075.3; = p.A464V on NM_001365.4) | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as rs747653625; called by mutect2, varscan2
- OR52L1 | c.487G>A p.G163R | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as rs769350807, COSV59988162; called by muse, mutect2
- PHACTR3 | c.934G>A p.G312R | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.84); catalogued as COSV63026539; called by muse, mutect2, varscan2
- SACS | c.13157G>A p.R4386Q | Missense Mutation (SNP) | VAF 43/165 reads (26%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.992); catalogued as rs781760041, COSV101207894, COSV66538963; called by muse, mutect2, varscan2
- CASS4 | c.1877C>G p.T626S | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CD163L1 | c.951G>T p.L317F | Missense Mutation (SNP) | VAF 45/226 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NRXN3 | c.2827G>T p.G943C (on ENST00000335750 / NM_001330195.2; = p.G570C on NM_004796.6) | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR10G2 | c.892C>A p.Q298K | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- TNRC6B | c.464C>A p.T155N | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- USH2A | c.6569G>T p.W2190L | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- USP29 | c.2197C>A p.Q733K | Missense Mutation (SNP) | VAF 150/335 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- ZNF347 | c.2102G>T p.R701I | Missense Mutation (SNP) | VAF 31/477 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.082); called by muse, mutect2
- KCNK9 | c.654G>A p.P218= | Silent (SNP) | VAF 39/109 reads (36%) | catalogued as rs763076662, COSV57278769; called by muse, mutect2, varscan2
- MYH1 | c.198T>A p.A66= | Silent (SNP) | VAF 21/227 reads (9%) | called by muse, mutect2
- PNLIPRP1 | c.1380G>A p.T460= | Silent (SNP) | VAF 18/108 reads (17%) | called by muse, mutect2, varscan2
- RANBP2 | c.3849T>C p.I1283= | Silent (SNP) | VAF 21/180 reads (12%) | called by muse, mutect2, varscan2
- SUGP1 | c.828C>T p.D276= | Silent (SNP) | VAF 14/90 reads (16%) | catalogued as rs758598757; called by muse, mutect2, varscan2
- LINC01596 | n.321A>T | RNA (SNP) | VAF 10/102 reads (10%) | called by muse, mutect2, varscan2
- LINC01666 | n.573A>G | RNA (SNP) | VAF 44/820 reads (5%) | called by muse, mutect2
